Gene-level copy-number profile of tumor specimen TCGA-CU-A5W6-01A from TCGA case TCGA-CU-A5W6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 70.4 years (25,706 days).
Specimen TCGA-CU-A5W6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.3ce6ef68-9ba5-473c-82dc-c982f48f6745.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CU-A5W6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fcf51e9c-e172-4876-881d-a2a43bff05cd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 581; copy number 2: 3,466; copy number 3: 15,805; copy number 4: 21,007; copy number 5: 15,394; copy number 6: 2,069; copy number 7: 406; copy number 8: 968; copy number 9: 86; copy number 12: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CU-A5W6-01A-11D-A288-01): tumor purity 0.47, ploidy 3.62, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr9:132,725,578–132,878,777, 1 gene (within-gene range 0–3): AK8.
- chr9:132,878,027–132,991,687, 6 genes (within-gene range 0–3): SPACA9, TSC1, GFI1B, MIR548AW, AL593851.1, RNU7-21P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:31,073,860–34,249,958, 86 genes, copy number 9 (broad region; genes not listed).
- chr17:69,961,568–71,298,218, 14 genes, copy number 12: LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1, AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P.

Autosomal genes at a single copy (total copy number 1): 581. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
